Surgical pathology report (de-identified scan), TCGA case TCGA-BF-A1PZ, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Cureline, specimen TCGA-BF-A1PZ-01A (Primary Tumor).

Project #
TSS #

ICD-0-3
Melanoma, NOS 8720/3
Site: Skin, NOS C44.9 3/12/11 *lw*

Index	Specimen label	Clinical Site #	Case #	Ethnicity (Race)	Clinical Diagnosis	DOB (mm/dd/yyyy)	Sex	Date of procurement	Anatomical Site	Tumor Location	Tissue Specification	Specimen Matrix	Specimen Format
1		52		Caucasian (White)	Melanoma		Female		Skin	Primary	Tumor	Tissue	Frozen
		52		Caucasian (White)	Melanoma		Female		Blood	n/a	normal	Blood	Frozen

Container	Number of containers	Amount/per container	Unit	Type of Procurement	Histological description	Grade	TNM Stage (T)	TNM Stage (N)	TNM Stage (M)	Prior Chemo / Hormonal Th	Chemo / Horm Th Details	Prior Radiation	Cellular Tumor %
cryomold	1	200	mg	Surgery	Melanoma	n/a	4	0	0	no	no	no	90
tube	1	4	ml	Blood draw	n/a	n/a	n/a	n/a	n/a	no	no	no	n/a

Case is (include):		

Source: NCI Genomic Data Commons file 4b8cdf83-2248-4c39-97ac-b7ec77086170 (TCGA-BF-A1PZ.1FAA6F42-BEE4-47B5-9D6A-87D310719766.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).